Surgical pathology report (de-identified scan), TCGA case TCGA-06-5414, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-5414-01A (Primary Tumor).

[page 1 of 2]
CLINICAL HISTORY

Right temporal brain tumor

OPERATIVE DIAGNOSES

Operation/Specimen: A: Glioblastoma, biopsy

B: Glioblastoma, biopsy

PATHOLOGICAL DIAGNOSIS:

A. and B. Brain, right cerebral tumor, excision biopsy: Glioblastoma (WHO Grade IV) (see comment).

COMMENT

Permanent sections confirm the frozen section diagnosis. Sections show a moderately pleomorphic, densely cellular glioma demonstrating frequent mitotic

figures, vascular proliferation and pseudopalisading necrosis. Reactive changes consistent with prior surgical intervention are also present.

Immunohistochemical stains show that the tumor cells are diffusely GFAP positive. The Ki-67 labeling index is up to approximately 30%.

Positive and negative controls show appropriate immunoreactivity.

Results of MGMT promoter methylation assay will be reported below in a procedure addenda.

Electronically Signed Out

PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED] Date Reported: [REDACTED]

Interpretation

NEGATIVE: No evidence of methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor paraffin block

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit from therapy with alkylating agents. Assessment of

MGMT promoter methylation status involves bisulfite treatment of DNA followed

by real-time PCR amplification (MethyLight) of methylated and unmethylated DNA

sequences. The analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the detection of methylated MGMT

[page 2 of 2]
promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the [REDACTED] laboratory as required by CLIA ' [REDACTED] regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

=====

INTRA-OPERATIVE CONSULTATION

A. Brain, right cerebral tumor, biopsy: High-grade glioma (consistent with glioblastoma). Frozen section and smears performed at [REDACTED] results reported to the Physician of Record. [REDACTED]

[REDACTED] Senior Staff Pathologist

GROSS DESCRIPTION

A. Glioblastoma, biopsy:

CONTAINER LABEL: Glioblastoma.

FIXATIVE: None. NO. PIECES: 2. SIZE/VOL: 3 mm each of gray, hemorrhagic brain tissue. Portions of each piece used for frozen section and smears.

CASSETTES: 1, [REDACTED]

B. Glioblastoma, biopsy:

CONTAINER LABEL: glioblastoma.

FIXATIVE: Formalin. NO. PIECES: 1. SIZE/VOL: 15 x 10 x 4 mm. CASSETTES: 1, [REDACTED]

ICD-9(s):

191.2 191.2

Histo Data

Part A: Glioblastoma, biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
FS H/E x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
TPS H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
mGFAP-DA x 1	3	[REDACTED]	
H/E x 1	3	[REDACTED]	
MGMT-curls x 1	3	[REDACTED]	
MIB1-DA x 1	3	[REDACTED]	
Rct 1 H/E x 1	3	[REDACTED]	

Part B: Glioblastoma, biopsy

Taken: [REDACTED]	Received: [REDACTED]		
Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	

Source: NCI Genomic Data Commons file dc21243f-198b-4226-9028-75b8eda0f4ab (TCGA-06-5414.40314DE5-33F1-4B29-85A1-D6292C6E2FC3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).